Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8341, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8341-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

- 1: SP: Kidney, left and renal vein thrombus, radical nephrectomy [REDACTED]
- 2: SP: Lymph nodes, para-aortic, excision [REDACTED]
- 3: SP: Vein, gonadal vein, segmental excision [REDACTED]
- 4: SP: Adrenal gland, left, excision [REDACTED]

DIAGNOSIS:

1. SP: Kidney, left and renal vein thrombus, radical nephrectomy [REDACTED]

Tumor Type:

Renal cell carcinoma - Chromophobe type
high grade with extensive necrosis (see comment)

Tumor Size:

Greatest diameter is 12.5 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis
Involves renal sinus fat
Involves renal hilar fat
Involves medium-sized veins in region of renal hilum

Renal Vein Invasion:

Identified

Surgical Margins:

Tumor is present at less than 1 mm from the stapled renal vein resection margin; the urothelium at the ureteral margin is partially denuded

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified
See part 4

Lymph Nodes:

Free of tumor
Number of nodes examined:1

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Comment: Although there is no sarcomatoid differentiation, there is focal significant epithelial anaplasia and a high nuclear grade. The tumor also demonstrates a high proliferation index evidenced by the Ki-67 immunostain

2. SP: Lymph nodes, para-aortic, excision

Lymph Nodes:

Number of nodes examined:30
Number of metastatic nodes:2
The largest metastatic node is 1.5cm
Perinodal (extracapsular) extension identified
The metastatic focus measures 1.2 cm in greatest extent

3. SP: Vein, gonadal vein, segmental excision

-Benign segment of vein

4. SP: Adrenal gland, left, excision

-Benign adrenal gland

Note:

This case was reviewed at the GU pathology consensus conference held

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	MIB-1 (Ki-67)	
	IRON	
	MEL (F-M)	
	IMM RECUT	
	NEG CONT	

Gross Description:

1). The specimen is received fresh labeled "left kidney and renal vein thrombus" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 633 g in total. The kidney measures 13.9 x 7.2 x 7.8 cm. The attached ureter measures 3.5 cm in length and 0.6 cm in diameter. The attached renal vein measures 4.5 cm in length and 3.5 cm in diameter. The ureteral margin is grossly unremarkable. However, immediately adjacent (less than 0.1 cm) to the renal vein staple line is a large yellowish-brown tumor thrombus measuring 3.5 cm in length and 2.5 cm in diameter. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a large necrotic multi-nodular tan-yellow tumor involving the superior and inferior poles, the renal pelvis and hilum, and the renal vein measuring 12.5 x 7.5 x 6.4 cm. The tumor appears to penetrate the capsule. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a poorly-defined cortico-medullary junction. The cortex measures 0.9 cm. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins (renal vein margin after removal of staples)

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TC -- tumor with capsule and perinephric fat

TK -- tumor with adjacent kidney

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

RP -- renal pelvis representative sections
K -- representative sections kidney

2). The specimen is received in formalin labeled "Para-aortic lymph nodes". It consists of multiple lymph nodes ranging from 0.2 x 0.2 cm up to 2.8 x 2.5 cm in greatest dimensions. Representative sections of the largest lymph nodes are submitted. The remainder of the lymph nodes are entirely submitted.

Summary of sections:

LN-whole lymph nodes

BLN-two bisected lymph nodes, one of which is inked black

LN1-lymph node number one

LN2-lymph node number two

LN3-lymph node three

3). The specimen is received in formalin labeled "Portion of left gonadal vein". It consists of a brown tan tubular structure measuring 5.5 cm in length and 0.5 cm in diameter, with attached yellow-tan fatty tissue measuring up to 1.5 cm in thickness. Cross sections show an unremarkable luminal aspect. Representative sections are submitted.

Summary of sections:

U-undesignated

4). The specimen is received in formalin labeled "Left adrenal gland". It consists of a 7 x 3 x 2 cm yellow-tan adrenal gland, with scant attached yellow-tan fatty tissue. The outer surface of the specimen shows a slightly ragged appearance. On cross sectioning, it shows unremarkable yellow parenchyma. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Kidney, left and renal vein thrombus, radical nephrectomy

Block	Sect. Site	PCs
1	K	1
2	RP	2
4	T	4
2	TC	2
1	THF	1
1	TK	1
1	TSF	1
1	UVM	1

Part 2: SP: Lymph nodes, para-aortic, excision

Block	Sect. Site	PCs
3	BLN	3
2	LN	2
1	LN1	1
1	LN2	1
1	LN3	1

Part 3: SP: Vein, gonadal vein, segmental excision

Block	Sect. Site	PCs
1	U	1

Part 4: SP: Adrenal gland, left, excision

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Block
2

Sect. Site
u

PCs
2

Source: NCI Genomic Data Commons file ed3534b3-dcbc-4ed5-908d-89274e854b65 (TCGA-KL-8341.1DB5A796-25F1-4A8C-B88C-08B5391FFE1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).